Gene-level copy-number profile of specimen HCM-CSHL-0809-C54-85A from HCMI case HCM-CSHL-0809-C54, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage IIIC1; FIGO stage: Stage III; Tumor grade: G3.
Specimen HCM-CSHL-0809-C54-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 10.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file cff39aac-fe93-4171-9813-c98ee4fa24af.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0809-C54-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,231 have no estimate.
https://portal.gdc.cancer.gov/files/89347eea-1753-479f-ad9a-f714e971f6d7

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 22; copy number 2: 4,671; copy number 3: 3,446; copy number 4: 44,461; copy number 5: 3,951; copy number 6: 1,429; copy number 7: 216; copy number 8: 51; copy number 9: 19; copy number 10: 84; copy number 11: 36; copy number 12: 2; copy number 289: 1.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr19:43,166,256–43,248,646, 3 genes (within-gene range 0–3): PSG5, PSG4, CEACAMP10.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 142 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:13,650,696–13,746,638, 1 gene, copy number 289 (within-gene range 5–289): LINC00620.
- chr3:173,396,284–174,286,644, 4 genes, copy number 11: NLGN1, AC092967.1, NLGN1-AS1, RN7SKP234.
- chr4:56,049,073–57,605,872, 39 genes, copy number 9–10 (within-gene range 7–10): CRACD, RNA5SP161, RNU6-197P, AC022267.1, MRPL22P1, AASDH, RPL7AP31, AC068620.1, PPAT, AC068620.2, AC068620.3, PAICS, SRP72, ARL9, THEGL, GLDCP1, HOPX, AC108215.1, RPL17P20, AC022483.1, RN7SL492P, RN7SL357P, SPINK2, Metazoa_SRP, Y_RNA, REST, AC069307.1, NOA1, POLR2B, RNU6-998P, IGFBP7, UBE2CP3, IGFBP7-AS1, AC111197.1, AC105390.1, RPS26P24, LINC02380, AC013724.1, AC107396.1.
- chr4:84,371,393–84,498,450, 2 genes, copy number 9–12: AC104063.1, NKX6-1.
- chr9:64,637,845–64,652,556, 1 gene, copy number 12: AL445665.1.
- chr17:37,084,992–39,564,907, 88 genes, copy number 10–11 (broad region; genes not listed).
- chr17:41,688,885–41,734,644, 5 genes, copy number 9: EIF1, GAST, HAP1, RNA5SP442, RN7SL399P.
- chr17:50,761,029–50,768,730, 2 genes, copy number 9: ANKRD40CL, MIR8059.

Autosomal genes at a single copy (total copy number 1): 22. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
